Surgical pathology report (de-identified scan), TCGA case TCGA-09-2043, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-2043-01A (Primary Tumor).

[page 1 of 5]
1. *Journal of the American Medical Association*, 2000; 283: 2689-2693.

B: Right tube, ovary, cervix, and uterus (fresh)

C: Omentum

D: Lymph node, right pelvic

1, Actin, alpha smooth muscle x 1, H&E, First x 1

F: Lymph node, right peri-aortic

G: Lymph node, left pelvic

H: Lymph node, left obturator

I: Bladder peritoneal biopsy

J: Right pelvic biopsy

FILE: 156A-2

L: Cul-de-sac

H&E, First X 1, Recut, Level 1 x 1, Recut, Level 2 x 1, Recut, Level 3 x 1

A. Left ovary and tube, salpingo-oophorectomy:

Page 1 of 6

B. Uterus, right ovary and right fallopian tube, total abdominal hysterectomy and salpingo-oophorectomy:

- Endometrium: Inactive pattern.

- Myometrium: Leiomyomas.

[page 2 of 5]
- Serosa: No significant pathologic abnormality.
- Cervix: No significant pathologic abnormality.
- Right ovary: No significant pathologic abnormality.
- Right fallopian tube: Paratubal cysts.
- C. Omentum, omentectomy: No tumor.
- D. Right pelvic lymph nodes, dissection:
1. No tumor (0/6).
2. Microscopic lymphangioleiomyoma.
- E. Right obturator lymph nodes, dissection: No tumor (0/2).
- F. Right periaortic lymph nodes, dissection: No tumor (0/6).
- G. Left pelvic lymph nodes, dissection: No tumor (0/4).
- H. Left obturator lymph nodes, dissection: No tumor (0/5).
- I. Bladder peritoneum, biopsy:
1. No tumor.
2. Acute and chronic inflammation.
- J. Right pelvic soft tissue, biopsy: No tumor.
- K. Left pelvic soft tissue, biopsy:
1. No tumor.
2. Acute and chronic inflammation.
- L. Cul de sac, biopsy:
1. No tumor.
2. Endosalpingiosis.
3. Organizing hemorrhagic adhesions.

Note: Ovarian Tumor Synoptic Comment

- **Location of tumor:** Unilateral, left ovary.
- **Type of tumor:** Serous carcinoma.
- **Grade of tumor:** 3.
- **Size of tumor:** 31 cm.
- **Surface of ovary:** Smooth.
- **Condition of capsule:** Ruptured.
- **Cut surface:** Solid and cystic, mainly cystic.
- **Color of solid areas:** Yellow.
- **Necrosis:** Focal.

Page 2 of 6

- **Lymphatic/vascular invasion:** None.
- **Sites of metastases in pelvis:** None.
- **Pelvic lymph nodes:** Negative, 0/17.
- **Sites of metastases in abdomen:** None.
- **Para-aortic lymph nodes:** Negative, 0/6.
- **Peritoneal cytology:** Results pending. Cytology CoPath accession number: [REDACTED]
- **Other findings:** None.
- **FIGO stage:** IC.
- **AJCC stage:** pT1N0MX, pending cytology results.

Immunohistochemical stain for smooth muscle myosin was performed on block D6 and is positive, supporting the diagnosis of lymphangioleiomyoma, an incidental benign entity that can present within pelvic lymph nodes.

Level sections were performed on block L1 and support the diagnoses.

Intraoperative Consult Diagnosis

[page 3 of 5]
FS1 (A) Left ovary, biopsy: Serous cystadenocarcinoma.

Clinical History

The patient is a [REDACTED] who presented with an elevated CA-125 and a large pelvic mass measuring 20 cm in size. The patient now undergoes exploratory laparotomy, total abdominal hysterectomy, and bilateral salpingo-oophorectomy, omentectomy, pelvic and peri-aortic lymph node dissections, as well as drainage of ascites and 7.5 cm of cyst fluid. Per the operative note, there was intraoperative spillage of cyst fluid during attempts to drain the fluid.

Gross Description

The specimen is received in twelve parts, each labeled with the patient's name and medical record number. Parts A-B are received fresh. Parts C-L are each received in formalin.

Part A, labeled "left tube and ovary," consists of a large disrupted tan-pink nodular, multicystic mass measuring 31 x 21 x 8.5 cm with attached purple-tan fallopian tube measuring 7.5 cm in length x 0.5 cm in diameter. The specimen weighs 1638 gm. The surface of the mass is pink-tan to yellow. The surface is smooth, and no nodules are identified on the surface. On cut section, the tumor is pink-tan to yellow and is multicystic and solid. The solid areas are yellow and soft. There is one focus of necrosis, measuring 6 cm in diameter. There are multiple areas of papillary growth, with small to large papillations seen. Multiple thin-walled cysts are also identified. No residual ovary is present. This mass extends to the resection margin, which is inked in blue. The mass is mostly cystic, with the solid area measuring approximately 14 x 11 x 10 cm. The fallopian tube contains several yellow-tan paratubal cysts. The fimbriae are lush. There is no tumor extension to the fallopian tube. Gross photographs are taken and a portion of the specimen is taken for tissue banking. A representative section of the mass is submitted for frozen section diagnosis 1, with the frozen section remnant submitted in cassette A1.

Additional representative sections are submitted as follows:

Cassette A2: Papillary areas.

Cassette A3: Papillary areas.

Cassette A4: Solid and papillary areas.

Cassettes A5-A8: Solid areas.

Cassettes A9-A11: Solid and papillary areas.

Cassettes A12-A14: Fallopian tube.

Cassette A15: Fimbriae. (h1b)

Part B is additionally labeled "right tube, ovary and cervix and uterus." It consists of an uterus and cervix with attached right adnexum. The specimen weighs 238 gm and measures 8 cm cornu to cornu, 11.9 cm superior to inferior and 4.8 cm anterior to posterior. The uterus sounds to 9.3 cm with a cervix measuring 2.7 x 2.7 cm. The cervix has a fish mouth os measuring 0.9 cm in diameter. On cut section, there are multiple myomas in the myometrium ranging in size from 0.5 cm to 3.8 cm in greatest dimension. The myomas are white-tan and solid with a whorled cut surface. The right adnexum measures 7 x 3 x 1.5 cm. It contains an ovary with a smooth, white-tan surface measuring 3.5 x 1.8 x

Page 3 of 6

1 cm. On cut section, it contains one apparently follicular white-tan cyst measuring approximately 2 cm. The fallopian tube measures 7 cm in length and ranges in diameter from 0.4-0.6 cm. It is studded with nodules ranging in size from 0.2-0.3 cm. Some of these nodules are solid and white-tan. Others are tan-gray and translucent and filled with mucinous material. The anterior of the uterus is inked blue and the posterior is inked black. Representative sections are submitted as follows:

Cassette B1: Anterior uterine wall full thickness.

Cassette B2: Anterior myoma.

Cassette B3: Anterior lower uterine segment.

Cassette B4: Anterior cervix.

Cassettes B5-B6: Posterior uterine wall, full thickness.

Cassette B7: Posterior myoma.

Cassette B8: Posterior lower uterine segment.

Cassette B9: Posterior cervix.

Cassette B10: Right ovary.

[page 4 of 5]
[REDACTED]

Cassettes B11-B12: Right fallopian tube. [REDACTED]

Part C is additionally labeled "3 - omentum," and consists of one soft, yellow-brown, irregular, unoriented, membranous adipose tissue fragment that is without nodules. The specimen measures 44.5 x 15.5 x 0.8 cm. Representative sections are submitted in cassettes C1-C4. [REDACTED]

Part D is additionally labeled "4 - right pelvic lymph nodes" and consists of one soft, yellow-brown, irregular, unoriented fibroadipose tissue fragment that measures 10.5 x 4.5 x 1 cm and contains multiple lymph node candidates that range from 1 to 4.5 cm in greatest diameter. Representative sections are submitted in cassettes D1-D7 as follows:

Cassette D1: Intact lymph node candidates.

Cassette D2: Single bisected lymph node candidate.

Cassette D3: Single bisected lymph node candidate.

Cassettes D4-D5: Single section of lymph node candidate submitted in two cassettes.

Cassettes D6-D7: Single section of lymph node candidate submitted in two cassettes. [REDACTED]

Part E is additionally labeled "right obturator node" and consists of one soft, yellow-brown, irregular, unoriented fibroadipose tissue fragment that measures 4 x 2 x 1 mm and contains two separate lymph node candidates that measure 1.8 and 3 cm in greatest diameter. Representative sections are submitted in cassettes E1-E3 as follows:

Cassette E1: Single bisected lymph node candidate.

Cassettes E2-E3: Single section of lymph node candidate submitted in two cassettes. [REDACTED]

Part F is additionally labeled "6 - right periaortic node" and consists of one soft, yellow-brown, irregular, unoriented fibroadipose tissue fragment that measures 5 x 1.3 x 0.7 cm and contains multiple lymph node candidates that range from 0.2 to 2 cm in greatest diameter. Representative sections are submitted in cassettes F1 and F2 as follows:

Cassette F1: Intact lymph node candidates.

Cassette F2: Single bisected lymph node candidate. [REDACTED]

Part G is additionally labeled "7 - left pelvic lymph nodes" and consists of one soft, yellow-brown, irregular, unoriented fibroadipose tissue that measures 7.5 x 4 x 1.3 cm and contains multiple lymph node candidates that range from 0.5 to 3.5 cm in greatest diameter. Representative sections are submitted in cassettes G1-G8 as follows:

Cassette G1: Intact lymph node candidates.

Cassette G2: Single bisected lymph node candidate.

Cassettes G3-G4: Single section of lymph node candidate submitted in two cassettes.

Cassettes G5-G8: Single section of lymph node candidate submitted in four cassettes. (jrc)

Part H is additionally labeled "8 - left obturator node" and consists of one soft, yellow-brown, irregular, unoriented fibroadipose tissue fragment that measures 6 x 2.6 x 1 cm and contains multiple lymph node candidates ranging from 1 to 3.2 cm in greatest diameter. Representative sections are submitted in cassettes H1-H6 as follows:

Cassette H1: Intact lymph node candidates.

Cassette H2: Single bisected lymph node candidate.

Cassette H3: Single section of lymph node candidate.

Cassette H4: Single section of lymph node candidate.

Cassettes H5-H6: Single section of lymph node candidate submitted in two cassettes. [REDACTED]

Part I is additionally labeled "9 - bladder peritoneum biopsy" and consists of one soft, yellow-brown, irregular, unoriented fibroadipose tissue fragment that measures 1 x 0.8 x 0.3 cm. The specimen is entirely submitted intact in cassette I1. [REDACTED]

Part J is additionally labeled "10 - right pelvic biopsy" and consists of one soft, yellow-white, irregular, unoriented fibroadipose tissue fragment that measures 0.8 x 0.3 x 0.3 cm. The specimen is entirely

[page 5 of 5]
[REDACTED]

submitted intact in cassette J1. [REDACTED]

Part K is additionally labeled "11 - left pelvic biopsy" and consists of one soft, brown-yellow, irregular, unoriented fibroadipose tissue fragment that measures 1 x 0.8 x 0.5 cm. The specimen is bisected and entirely submitted in cassette K1. [REDACTED]

Part L is additionally labeled "12 - cul-de-sac" and consists of one brown-white, irregular, unoriented fibroadipose tissue fragment that measures 1.3 x 1.2 x 0.3 cm. The specimen is entirely submitted intact in cassette L1. [REDACTED]

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED]

[REDACTED] They have not been cleared or approved by the U. S. Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing.

[REDACTED]

Other Specimens

[REDACTED]

Specimen(s) Received: A: Diaphragmatic Washing, B: Ascitic Fluid

Final Diagnosis

A: Diaphragmatic Washing

ADENOCARCINOMA.

See Below.

Page 5 of 6

B: Ascitic Fluid

ADENOCARCINOMA.

See Below.

[REDACTED]

[REDACTED]

Specimen(s) Received: Cervix, biopsy

Final Diagnosis

Cervix, biopsy: Cervical mucosa with mild acute and chronic inflammation, no carcinoma identified; see comment.

[REDACTED]

Source: NCI Genomic Data Commons file ab8c1ff0-5cd9-4438-bd95-7f2c98b916e4 (TCGA-09-2043.1FA4E0B8-344F-4EBB-B150-C3ACE0EC4A00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).